Somatic mutation profile of tumor specimen TCGA-Z6-AAPN-01A (aliquot TCGA-Z6-AAPN-01A-11D-A403-09) from TCGA case TCGA-Z6-AAPN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 57.3 years (20,926 days).
Specimen TCGA-Z6-AAPN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e632f78a-3e12-4f05-8d58-1f9a1aa575b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z6-AAPN-10A (Blood Derived Normal), aliquot TCGA-Z6-AAPN-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bcb1860-9f94-4858-9ec9-831f31ef2a5a

The open-access MAF lists 369 somatic variants for this specimen: 293 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 71, Nonsense Mutation 26, Splice Region 4, Splice Site 3, 3'UTR 2, Frame Shift Ins 1, In Frame Del 1, RNA 1, Frame Shift Del 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC3A1 | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs1361526419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2
- ABCC4 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV65313602; called by muse, mutect2, varscan2
- AC006059.2 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs757265443, COSV59609165; called by muse, mutect2, varscan2
- ACAD10 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58158491; called by muse, mutect2, varscan2
- ACSL4 | c.1345C>G p.Q449E (on ENST00000340800 / NM_022977.2; = p.Q408E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61615285; called by muse, mutect2, varscan2
- ADAM23 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs111649087; called by muse, mutect2, varscan2
- AHNAK | c.3850G>T p.D1284Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99946940; called by muse, mutect2, varscan2
- AHNAK | c.3139G>C p.E1047Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1220953359; called by muse, mutect2, varscan2
- AKAP9 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV62360513; called by muse, mutect2, varscan2
- ANGPTL3 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV51994852; called by muse, mutect2, varscan2
- ARHGEF17 | c.5674G>C p.E1892Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs372726461; called by muse, mutect2, varscan2
- ASPA | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023014; called by muse, mutect2, varscan2
- ASPH | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.232); catalogued as COSV100727545; called by muse, mutect2, varscan2
- ATM | c.6046G>C p.D2016H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53762311, COSV53785229, COSV53787203; called by muse, mutect2, varscan2
- B3GAT1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs368413334; called by muse, mutect2, varscan2
- BCHE | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746209182, COSV100012948; called by muse, mutect2, varscan2
- BDP1 | c.6559G>A p.E2187K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1366498941; called by muse, mutect2, varscan2
- C12orf29 | c.901_904del p.K301Vfs*7 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | catalogued as rs754202444; called by mutect2, pindel, varscan2
- CASR | c.2164G>C p.E722Q (on ENST00000490131; = p.E799Q on NM_000388.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM013357, COSV56136235; called by muse, mutect2, varscan2
- CDC20 | c.828G>C p.W276C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60523048; called by muse, mutect2, varscan2
- CDH7 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV59894440; called by muse, mutect2, varscan2
- CFAP46 | c.7245C>A p.F2415L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV99583853; called by muse, mutect2
- CHML | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100087318; called by muse, mutect2, varscan2
- CHMP6 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs749930438; called by muse, mutect2, varscan2
- CLSTN1 | c.1637C>T p.S546F (on ENST00000377298 / NM_001009566.3; = p.S536F on NM_014944.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63651292; called by muse, mutect2, varscan2
- CNIH2 | c.66_68del p.F23del | In Frame Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs1448131918; called by pindel, varscan2
- COL13A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs201112703; called by muse, mutect2, varscan2
- COL16A1 | c.3857G>C p.R1286T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV54709691; called by muse, mutect2, varscan2
- CYP2C9 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1210894054; called by muse, mutect2
- DDX60L | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1031967890; called by muse, mutect2, varscan2
- DSG4 | c.2776G>C p.D926H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57390620; called by muse, mutect2, varscan2
- ENPP1 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs768378653; called by muse, mutect2, varscan2
- EP400 | c.1909C>G p.Q637E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.215); catalogued as COSV100202543; called by muse, mutect2, varscan2
- FATE1 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.3); catalogued as COSV64849274; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201738008; called by mutect2, varscan2
- FPGT-TNNI3K | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs567503494, COSV100437764, COSV58547926; called by muse, mutect2, varscan2
- FRYL | c.2791G>C p.E931Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV99977534; called by muse, mutect2, varscan2
- GATAD1 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV55319283; called by muse, mutect2
- GCLM | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV64686908; called by muse, mutect2, varscan2
- GLYR1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs1419637045, COSV58929125; called by muse, mutect2
- GTF2IRD1 | c.2052G>C p.K684N (on ENST00000265755 / NM_016328.3; = p.K669N on NM_005685.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV99733961; called by muse, mutect2, varscan2
- HHIPL2 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs140791930; called by muse, mutect2, varscan2
- HLA-B | c.343+2T>C p.X115_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV69522964; called by muse, mutect2, varscan2
- HLA-B | c.343+1G>T p.X115_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as COSV69520345, COSV69521733; called by muse, mutect2, varscan2
- INHA | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1156448678, COSV54730076; called by muse, mutect2, varscan2
- KIAA1549L | c.4783C>T p.P1595S (on ENST00000321505; = p.P1892S on NM_012194.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58590200; called by muse, mutect2, varscan2
- KIAA1549L | c.4784C>T p.P1595L (on ENST00000321505; = p.P1892L on NM_012194.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762094891, COSV100382222; called by muse, mutect2, varscan2
- KIF11 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs149407589; called by muse, mutect2
- KLB | c.2402C>G p.S801W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV57302391; called by muse, mutect2, varscan2
- KLHL4 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV64140345; called by muse, mutect2, varscan2
- LRPPRC | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs996514783; called by muse, mutect2, varscan2
- LRSAM1 | c.2069G>A p.C690Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100031790; called by muse, mutect2, varscan2
- LYPD4 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); catalogued as rs368266342, COSV58027855; called by muse, mutect2, varscan2
- MAJIN | c.618G>C p.R206S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV54164873; called by muse, mutect2, varscan2
- MAOB | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100956177; called by muse, mutect2, varscan2
- MECOM | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV72110006; called by muse, mutect2, varscan2
- MECP2 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs782115829; called by muse, mutect2, varscan2
- MN1 | c.3489G>C p.Q1163H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100180237; called by muse, mutect2, varscan2
- MUC17 | c.10595C>G p.S3532C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1249706913; called by muse, mutect2, varscan2
- MYCBP2 | c.9411C>G p.I3137M (on ENST00000357337; = p.I3175M on NM_015057.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs776257927; called by muse, mutect2, varscan2
- MYO1F | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs201646155, COSV57791852; called by muse, mutect2, varscan2
- NCAM2 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs763784898, COSV53059389; called by muse, mutect2
- NUAK2 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV65682607; called by muse, mutect2
- OGDH | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV56048712, COSV56053761, COSV99758179; called by muse, mutect2, varscan2
- OR1C1 | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101376183; called by muse, mutect2, varscan2
- OR51S1 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV59057631; called by muse, mutect2
- OR7C2 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.027); catalogued as rs1174243683, COSV99934531; called by muse, mutect2, varscan2
- PCDHGA1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65297178; called by muse, mutect2
- PCDHGA3 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); catalogued as rs762455729, COSV53980221, COSV54036945; called by muse, mutect2
- PCDHGA9 | c.997G>C p.V333L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.308); catalogued as rs1167033357, COSV54071455; called by mutect2, varscan2
- PCYT1A | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs760187621; called by muse, mutect2, varscan2
- PDLIM2 | c.910C>T p.R304W (on ENST00000397760; = p.R554W on NM_021630.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147368012; called by muse, mutect2, varscan2
- PDPN | c.169G>A p.E57K (on ENST00000621990; = p.E133K on NM_006474.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs778306499, COSV53846700; called by muse, mutect2, varscan2
- PJVK | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV57870832; called by muse, mutect2, varscan2
- PLEKHH2 | c.520T>G p.S174A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs746212226; called by muse, varscan2
- PLPPR4 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV64564792, COSV64566224; called by muse, mutect2, varscan2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2
- PNLIPRP2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs868906602; called by muse, mutect2, varscan2
- POLDIP3 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52808599; called by muse, mutect2, varscan2
- PRRX1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.757); catalogued as COSV53411702; called by muse, mutect2, varscan2
- RAB3IL1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1314919374, COSV100076858; called by muse, mutect2, varscan2
- RBPJL | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV59212900; called by muse, mutect2, varscan2
- RNF207 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); catalogued as COSV65008567; called by muse, mutect2, varscan2
- RPS13 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV57180427; called by muse, mutect2
- RTP4 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52018687; called by muse, mutect2, varscan2
- SCAMP3 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as COSV100226827; called by muse, mutect2, varscan2
- SEC24A | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.051); catalogued as rs769794390; called by muse, mutect2, varscan2
- SEMA3A | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs753997365; called by muse, mutect2, varscan2
- SEPTIN1 | c.502G>C p.E168Q (on ENST00000321367; = p.E121Q on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV58442214; called by muse, mutect2, varscan2
- SEPTIN14 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.88); catalogued as rs1307552942, COSV66426411; called by muse, mutect2, varscan2
- SHROOM2 | c.4597G>C p.E1533Q | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV66606342; called by muse, mutect2, varscan2
- SLC25A39 | c.976C>G p.R326G (on ENST00000377095 / NM_001143780.3; = p.R318G on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56587155; called by muse, mutect2, varscan2
- SLC6A19 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs200597791, COSV58674658; called by muse, mutect2, varscan2
- SLC6A3 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54364043; called by muse, mutect2
- SPON1 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100115332; called by muse, mutect2, varscan2
- SREBF1 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99888932; called by muse, mutect2, varscan2
- STK11IP | c.2245C>G p.P749A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs776907199; called by muse, varscan2
- STXBP5L | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56515352, COSV56532416; called by muse, mutect2, varscan2
- TBX15 | c.673G>C p.E225Q (on ENST00000369429 / NM_001330677.2; = p.E119Q on NM_152380.3) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874162; called by muse, mutect2, varscan2
- TECPR1 | c.1505C>G p.S502W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV101130191, COSV65782670; called by muse, mutect2, varscan2
- TENT2 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV57134779; called by muse, mutect2, varscan2
- TGS1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs754206400, COSV52700594; called by muse, mutect2, varscan2
- TIE1 | c.1785G>C p.E595D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.325); catalogued as COSV65251551; called by muse, mutect2
- TIMELESS | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV57513740; called by muse, mutect2, varscan2
- TMC2 | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100727442, COSV62656463; called by muse, mutect2, varscan2
- TMEM154 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58592015; called by muse, mutect2, varscan2
- TPTE2 | c.557G>T p.R186I (on ENST00000400230 / NM_199254.2; = p.R109I on NM_130785.3) | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55025003, COSV55028348; called by muse, mutect2, varscan2
- TRIL | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs746364113, COSV59867117; called by muse, mutect2, varscan2
- TRIM60 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV100593936; called by muse, mutect2, varscan2
- TRIP12 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99390651; called by muse, mutect2, varscan2
- TTC30A | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs770640849; called by mutect2, varscan2
- TUB | c.1245G>C p.Q415H (on ENST00000299506 / NM_177972.3; = p.Q470H on NM_003320.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs1422469677; called by muse, mutect2, varscan2
- URM1 | c.33C>T p.F11= | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as rs752847603; called by muse, varscan2
- USP33 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62470153; called by muse, mutect2, varscan2
- WDPCP | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as rs1354054730; called by muse, mutect2, varscan2
- WDR64 | c.2808C>A p.S936R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs1189764750; called by muse, mutect2, varscan2
- ZBTB7B | c.130G>C p.E44Q (on ENST00000292176; = p.E78Q on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV52692164; called by muse, mutect2, varscan2
- ZCCHC24 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64887498; called by muse, mutect2, varscan2
- ZNF420 | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58492537; called by muse, mutect2, varscan2
- ZNF773 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV56587787; called by muse, mutect2, varscan2
- A4GNT | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- AARD | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- ABCA1 | c.3476C>G p.S1159C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by mutect2, varscan2
- ACVR1B | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADGRB2 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADGRB3 | c.4267G>C p.D1423H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ADGRV1 | c.3778G>C p.E1260Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AGR3 | c.359T>G p.M120R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AHNAK | c.4513G>C p.D1505H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AKAP9 | c.2264T>G p.L755* | Nonsense Mutation (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- AKAP9 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ANAPC13 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ANAPC2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ANKRD29 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKS1B | c.2644G>A p.D882N (on ENST00000547776 / NM_152788.4; = p.D108N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APPBP2 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ARID5B | c.2976G>C p.M992I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATP2B1 | c.2438C>G p.A813G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- BICD2 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- BRD4 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BST1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- BTAF1 | c.3956C>G p.S1319* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- C10orf88 | c.1103G>C p.G368A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C11orf80 | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- CACNA1C | c.4735G>C p.E1579Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CANX | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- CCDC59 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH17 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CENPF | c.3068T>G p.L1023R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CENPH | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP104 | c.567G>A p.R189= | Splice Region (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- CFAP65 | c.4763C>T p.A1588V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHD1L | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CHRNA5 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CLSPN | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- COL14A1 | c.3676G>C p.D1226H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- COL4A2 | c.1855G>C p.G619R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRNKL1 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CSRNP2 | c.1578G>C p.Q526H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CWC22 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- CYB5A | c.404G>T p.*135Lext*73 | Nonstop Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- CYLC1 | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- CYLC1 | c.1745C>G p.S582* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- DCAF17 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DDX21 | c.1685G>C p.R562P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DDX24 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DDX5 | c.1457G>C p.R486T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DEFB108B | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- DHX9 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLG5 | c.4510T>A p.F1504I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAJC28 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DNMT3A | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DYNC2H1 | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB2 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ELF1 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- EPOR | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GABRB1 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GFM1 | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- GFRA1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2
- GOLGB1 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR156 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN3B | c.1901G>T p.S634I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.969); called by muse, mutect2
- HCN4 | c.3465G>T p.K1155N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR5B | c.4988G>C p.G1663A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELB | c.723G>C p.L241F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- HNRNPH1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, varscan2
- HOOK2 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- HOXD12 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IFT172 | c.3288G>C p.K1096N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- INF2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JAG2 | c.1172C>G p.S391W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCMF1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KCNK13 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- KIF1B | c.4973C>G p.S1658C (on ENST00000377086 / NM_001365952.1; = p.S1612C on NM_015074.3) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KMT2D | c.10672G>T p.E3558* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- KRT78 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRTAP5-7 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- KYAT3 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2
- LAPTM5 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LCE3C | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- LNX1 | c.772G>A p.E258K (on ENST00000263925 / NM_001126328.3; = p.E162K on NM_032622.2) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LRP2BP | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC32 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LYN | c.1268A>C p.K423T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MACF1 | c.8461C>G p.Q2821E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- MED19 | c.423C>G p.F141L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MMP2 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MRPS36 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MTG1 | c.232C>G p.H78D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC17 | c.10493C>G p.S3498C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYBPC1 | c.2404A>G p.T802A (on ENST00000550270 / NM_206820.2; = p.T809A on NM_002465.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NCKAP1L | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- NCKAP5L | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFB8 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NHS | c.3562G>C p.E1188Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); called by muse, varscan2
- NOX4 | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OPA1 | c.3025G>C p.E1009Q (on ENST00000361510 / NM_130837.3; = p.E954Q on NM_015560.3) | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8K3 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OXCT2 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- OXSR1 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- PATJ | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2
- PCDHGB7 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PCK1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDGFRA | c.1261_1265dup p.D422Efs*14 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PDS5A | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- PFKM | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PGBD2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHKB | c.1704T>G p.I568M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIGK | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLEK | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POGZ | c.3883G>C p.D1295H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLQ | c.3970C>G p.L1324V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- POLR1B | c.2272-1G>A p.X758_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- PPL | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PPP2R2B | c.997T>C p.Y333H (on ENST00000394409; = p.Y399H on NM_181674.2) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- PRDM1 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PRDM10 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); called by mutect2, varscan2
- PREX2 | c.4362C>G p.D1454E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRG4 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PRRC1 | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PSMA5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTPDC1 | c.2221G>C p.E741Q (on ENST00000375360 / NM_177995.3; = p.E793Q on NM_152422.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PTPN20 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- RAI14 | c.1109T>C p.L370S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- RBM6 | c.1631G>C p.R544P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RFX7 | c.307G>C p.D103H (on ENST00000559447 / NM_001368074.1; = p.D200H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RMND5B | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPL10L | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPUSD2 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEC61A1 | c.121A>C p.I41L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGSM2 | c.2035G>C p.E679Q (on ENST00000426855 / NM_001098509.2; = p.E724Q on NM_014853.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SIM1 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIX4 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- SLC35G5 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, varscan2
- SLC5A3 | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SLC6A3 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- SLC7A9 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- SLF2 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SMARCA2 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMIM7 | c.69G>C p.L23= | Splice Region (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- SOX11 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SPEN | c.10339C>G p.L3447V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SRCIN1 | c.697G>A p.E233K (on ENST00000621492; = p.E199K on NM_025248.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SRSF12 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- STK36 | c.1915G>T p.G639* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2
- STX1B | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SUPT20HL1 | c.689T>G p.M230R | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SYNCRIP | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TAF15 | c.1550G>C p.G517A (on ENST00000605844 / NM_139215.3; = p.G514A on NM_003487.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- TCHHL1 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TEX55 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TMEM94 | c.3636C>G p.P1212= | Splice Region (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.2456C>G p.P819R (on ENST00000452346; = p.P693R on NM_001042575.2) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.867); called by muse, mutect2
- TMTC4 | c.1789C>G p.L597V (on ENST00000376234 / NM_001350577.2; = p.L616V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- TOMM70 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUT1 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2
- U2SURP | c.2726C>G p.S909C | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- UBAP2 | c.2246C>G p.S749* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- UBE4B | c.3000T>A p.F1000L (on ENST00000343090 / NM_001105562.3; = p.F871L on NM_006048.5) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.047); called by muse, mutect2
- UBR5 | c.7785C>G p.F2595L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- VPS35L | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- VWA5A | c.1494C>G p.I498M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2
- ZFPM2 | c.1048T>A p.F350I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.292); called by muse, mutect2
- ZNF251 | c.974A>C p.E325A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- ZNF267 | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF281 | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ZNF521 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF622 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZNF829 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- AHCTF1 | c.573A>G p.A191= (on ENST00000366508; = p.A165= on NM_015446.5) | Silent (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- AKAP13 | c.792A>G p.E264= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs139228217; called by muse, mutect2, varscan2
- ANO2 | c.2841G>C p.L947= (on ENST00000356134 / NM_001278597.3; = p.L951= on NM_001278596.3) | Silent (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- ASTN1 | c.933G>A p.V311= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- BAG6 | c.597G>A p.Q199= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- C1R | c.1500C>T p.R500= (on ENST00000536053 / NM_001354346.2; = p.R486= on NM_001733.7) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs777050185; called by muse, varscan2
- CCDC40 | c.345G>A p.P115= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs561961621, COSV53896702; called by mutect2, varscan2
- CDC42EP4 | c.435G>A p.K145= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV59964283; called by muse, mutect2, varscan2
- CLPTM1L | c.1012C>T p.L338= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs1411465184; called by muse, mutect2
- CNR1 | c.9G>A p.S3= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs371432780; called by muse, mutect2, varscan2
- COL12A1 | c.1098C>T p.V366= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- COL6A3 | c.6723G>C p.L2241= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- COLEC12 | c.933G>T p.L311= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- CSE1L | c.1782C>T p.L594= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- CYFIP2 | c.1926C>G p.L642= (on ENST00000616178 / NM_001291722.2; = p.L617= on NM_014376.4) | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs367974123, COSV59035448; called by muse, mutect2, varscan2
- DISP3 | c.375G>A p.A125= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs768397889; called by muse, mutect2, varscan2
- DYNC1I1 | c.1686C>T p.L562= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- FANCD2 | c.3705C>T p.F1235= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- FRG2 | c.172A>C p.R58= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- GAB4 | c.18C>T p.P6= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- GPR180 | c.714A>C p.P238= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV65385938; called by muse, mutect2, varscan2
- HOGA1 | c.816C>T p.L272= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- IFT172 | c.2514C>T p.F838= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53130653; called by muse, mutect2, varscan2
- LILRB4 | c.417C>T p.S139= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs541287083, COSV54403159; called by muse, mutect2, varscan2
- MC4R | c.639C>G p.V213= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- MNT | c.1656G>T p.V552= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- MRPL13 | c.108T>C p.S36= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV59961579; called by muse, mutect2, varscan2
- MRPS28 | c.156C>T p.F52= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1345731655; called by muse, mutect2
- MXD3 | c.570C>T p.F190= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs533160184, COSV57463294; called by muse, mutect2, varscan2
- MYO1D | c.2364C>A p.L788= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- MYO5C | c.2913G>A p.Q971= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- NANS | c.375G>A p.L125= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV52963404; called by muse, mutect2, varscan2
- NKD2 | c.255C>T p.L85= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as rs948633858; called by muse, mutect2, varscan2
- NPAP1 | c.651A>T p.S217= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- NSMF | c.1485C>G p.L495= (on ENST00000371475 / NM_001130969.3; = p.L493= on NM_015537.4) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs780154049; called by muse, mutect2, varscan2
- OPLAH | c.555C>T p.R185= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- OR3A3 | c.960G>A p.L320= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- OR4C3 | c.414C>G p.L138= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV60588838, COSV60590243; called by muse, mutect2
- OR5I1 | c.345C>T p.F115= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs768904558, COSV56886143; called by muse, mutect2, varscan2
- PEX1 | c.1137G>A p.E379= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV50398101; called by muse, mutect2
- PGAP1 | c.547T>C p.L183= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- PGM2 | c.321C>T p.A107= | Silent (SNP) | VAF 55/224 reads (25%) | called by muse, mutect2, varscan2
- POLE | c.3750C>A p.P1250= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- PPARD | c.972C>T p.F324= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- PPARG | c.687C>T p.I229= (on ENST00000287820 / NM_015869.5; = p.I199= on NM_005037.7) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs755427537; called by muse, mutect2, varscan2
- PRAMEF15 | c.642G>T p.V214= | Silent (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2, varscan2
- PRDM8 | c.528C>T p.F176= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PRDM9 | c.2460C>T p.L820= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1340944986; called by muse, varscan2
- PREPL | c.171G>A p.K57= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- PTPRK | c.1968C>A p.V656= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- RADIL | c.1116C>A p.L372= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- RBM6 | c.3000G>C p.L1000= | Silent (SNP) | VAF 25/118 reads (21%) | called by muse, mutect2, varscan2
- RPRD2 | c.3399A>G p.T1133= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs764154888; called by muse, mutect2, varscan2
- SEZ6L2 | c.987C>T p.I329= (on ENST00000308713 / NM_001114099.3; = p.I259= on NM_012410.4) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs776839200; called by muse, mutect2, varscan2
- SF3A1 | c.2370G>C p.G790= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53170674; called by muse, mutect2, varscan2
- SI | c.5359C>T p.L1787= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100013880; called by muse, mutect2, varscan2
- SLC11A2 | c.702G>A p.R234= (on ENST00000394904 / NM_001379455.1; = p.R205= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- SLC25A45 | c.369C>T p.I123= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs370182084; called by muse, mutect2, varscan2
- SLC44A5 | c.96C>T p.A32= | Silent (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- SLC6A9 | c.606C>T p.I202= (on ENST00000360584 / NM_201649.4; = p.I148= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1470418671; called by muse, mutect2, varscan2
- SLCO6A1 | c.1087C>T p.L363= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV65814991; called by muse, mutect2, varscan2
- SMG8 | c.1083G>A p.V361= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- SNX30 | c.453C>G p.L151= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SPANXB1 | c.162G>A p.S54= | Silent (SNP) | VAF 81/715 reads (11%) | called by muse, mutect2, varscan2
- SPOCK3 | c.702G>A p.L234= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100693174; called by muse, mutect2, varscan2
- SPTAN1 | c.4722G>A p.A1574= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs886972447, COSV100823906; called by muse, mutect2, varscan2
- TAS1R2 | c.1965C>A p.I655= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs751000756, COSV64744620; called by muse, mutect2, varscan2
- TPX2 | c.381G>A p.Q127= | Silent (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- TRIO | c.3198G>A p.Q1066= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV60076700; called by muse, mutect2, varscan2
- TRPC6 | c.2334G>A p.L778= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- UBE2E3 | c.66G>A p.A22= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1252106061, COSV66585836; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829074 C>T | 3'Flank (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2507C>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- GRIA3 | c.2440-2661C>T | Intron (SNP) | VAF 38/73 reads (52%) | catalogued as COSV99991414; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1263G>A | RNA (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- VMP1 | c.*1376G>T | 3'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
